Somatic mutation profile of tumor specimen TCGA-V4-A9EZ-01A (aliquot TCGA-V4-A9EZ-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EZ, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 78.4 years (28,619 days).
Specimen TCGA-V4-A9EZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc575239-1f1e-4d1f-bf4f-4dc3ac6221d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EZ-10A (Blood Derived Normal), aliquot TCGA-V4-A9EZ-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16cc5d95-e7f4-4c64-a409-bfef1a491e1c

The open-access MAF lists 23 somatic variants for this specimen: 13 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 12, Silent 10, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 50/87 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 31/74 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519961, COSV59205431, COSV59206122, COSV59206364; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APEX2 | c.984C>A p.F328L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV58193316; called by muse, mutect2, varscan2
- CAT | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs746357360; called by muse, mutect2, varscan2
- CDH4 | c.2638G>A p.V880I | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.993); catalogued as rs780992540, COSV64644940; called by muse, mutect2
- COL14A1 | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as rs1238741811; called by muse, mutect2, varscan2
- DSC1 | c.2195del p.N732Ifs*2 | Frame Shift Del (DEL) | VAF 28/90 reads (31%) | called by mutect2, pindel, varscan2
- NECAP1 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PYCR2 | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPIND1 | c.829G>C p.A277P | Missense Mutation (SNP) | VAF 162/338 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SLFN11 | c.2441G>A p.S814N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- TMEM39A | c.578T>A p.F193Y | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TNS3 | c.824G>C p.G275A | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ALOX15 | c.1182A>T p.R394= | Silent (SNP) | VAF 32/123 reads (26%) | catalogued as rs1472437416; called by muse, mutect2, varscan2
- ARHGAP4 | c.1983G>A p.G661= | Silent (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- DCAF1 | c.1569C>G p.A523= | Silent (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- KANK3 | c.2238G>A p.R746= | Silent (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- MYOF | c.300G>A p.P100= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs756928666, COSV63700233; called by muse, mutect2, varscan2
- OPA3 | c.360C>T p.N120= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as rs1308359391, COSV54400771; called by muse, mutect2
- PALM2AKAP2 | c.1104G>T p.L368= (on ENST00000259318 / NM_001136562.3; = p.L599= on NM_007203.5) | Silent (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- PPID | c.372C>T p.G124= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs747950446; called by muse, mutect2, varscan2
- ZBTB21 | c.2775G>A p.E925= | Silent (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
- ZNF479 | c.753C>T p.S251= | Silent (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
